Somatic mutation profile of tumor specimen TCGA-ER-A19E-06A (aliquot TCGA-ER-A19E-06A-11D-A197-08) from TCGA case TCGA-ER-A19E, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 36.5 years (13,331 days).
Specimen TCGA-ER-A19E-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10d500a4-04d1-4256-8239-7ee1e673a1e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19E-10A (Blood Derived Normal), aliquot TCGA-ER-A19E-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d1d32fe-86b7-4d61-a6ca-5ee992f5653f

The open-access MAF lists 541 somatic variants for this specimen: 362 protein-altering or splice-affecting, 164 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 322, Silent 164, Nonsense Mutation 26, RNA 8, Intron 5, Splice Region 5, Frame Shift Del 4, Splice Site 3, Translation Start Site 1, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/132 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.70C>A p.R24S | Missense Mutation (SNP) | VAF 24/28 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs11547328, CM960267, COSV56984534, COSV56985244; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNAT1 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as rs774214573, COSV50031400; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 23/37 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 16/17 reads (94%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB1 | c.2659A>G p.K887E | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55955502; called by muse, mutect2
- ABCC2 | c.632G>A p.S211N | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.776); catalogued as rs143584410; called by muse, mutect2, varscan2
- ABCG8 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 188/446 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs142346631, COSV55394571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABLIM3 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58645302; called by muse, mutect2, varscan2
- AC090517.4 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1382450059, COSV50997111; called by muse, mutect2, varscan2
- ACD | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.018); catalogued as COSV99537499; called by muse, mutect2, varscan2
- ADAM19 | c.2480G>A p.R827K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV57433346; called by muse, mutect2, varscan2
- ADAM22 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as rs778859953, COSV55981739; called by muse, mutect2, varscan2
- ADAMTS17 | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51485516; called by muse, mutect2, varscan2
- ADCY1 | c.2234T>C p.F745S | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV52037518; called by muse, mutect2, varscan2
- ADD2 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs781930613, COSV52464563; called by muse, mutect2, varscan2
- ADGRE1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV51677667; called by muse, mutect2, varscan2
- AFF4 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV54796497; called by muse, mutect2, varscan2
- AKR1B15 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV71152351; called by muse, mutect2, varscan2
- ALK | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs56077855, COSV66575550; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALMS1 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV52513880; called by muse, mutect2, varscan2
- ANAPC5 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 116/245 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV55843623; called by muse, mutect2, varscan2
- ANK3 | c.2024G>T p.G675V | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55066561; called by muse, mutect2, varscan2
- ANKRD30A | c.734C>T p.A245V (on ENST00000611781; = p.A189V on NM_052997.2) | Missense Mutation (SNP) | VAF 83/111 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV64614266; called by muse, mutect2, varscan2
- AOX1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV65980466; called by muse, mutect2, varscan2
- APCS | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54818578; called by muse, mutect2, varscan2
- APOB | c.2262A>G p.I754M | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV51926032; called by muse, varscan2
- ARHGEF37 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV61369289; called by muse, mutect2, varscan2
- ARID2 | c.2969C>T p.S990L | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.163); catalogued as rs758368727, COSV57604758; called by muse, varscan2
- ATG7 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61611308, COSV61613839; called by muse, mutect2, varscan2
- ATP1B3 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 61/90 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV53950434; called by muse, mutect2, varscan2
- ATP8B4 | c.3368C>T p.S1123L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs775773188, COSV52718791, COSV99462831; called by muse, mutect2, varscan2
- BAHD1 | c.2055C>T p.P685= | Splice Region (SNP) | VAF 20/56 reads (36%) | catalogued as COSV69084217; called by muse, mutect2, varscan2
- BCAS3 | c.1763C>T p.S588F (on ENST00000390652 / NM_001353144.2; = p.S573F on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV66776901; called by muse, mutect2, varscan2
- BEND7 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 41/54 reads (76%) | PolyPhen benign (0.06); catalogued as COSV61989818; called by muse, mutect2, varscan2
- BIK | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 56/68 reads (82%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as COSV53337897; called by muse, mutect2, varscan2
- BNC2 | c.773T>G p.V258G | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV66151083; called by muse, mutect2, varscan2
- BRI3BP | c.322A>T p.N108Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV58296585; called by muse, mutect2, varscan2
- BTBD9 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 68/108 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV58430277; called by muse, mutect2, varscan2
- C11orf42 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.244); catalogued as rs752623273; called by muse, mutect2, varscan2
- C1QTNF2 | c.419C>T p.P140L (on ENST00000393975; = p.P95L on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.194); catalogued as COSV67432944; called by muse, mutect2, varscan2
- C1orf94 | c.1072C>T p.P358S (on ENST00000488417 / NM_001134734.2; = p.P168S on NM_032884.5) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV100975191, COSV64914504; called by muse, mutect2, varscan2
- C8A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs777495880, COSV63483150; called by mutect2, varscan2
- CACNA1A | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64202779; called by muse, mutect2, varscan2
- CACNA1E | c.6568G>A p.E2190K (on ENST00000367573 / NM_001205293.3; = p.E2147K on NM_000721.4) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as rs751185780, COSV62401289; called by muse, mutect2, varscan2
- CALB1 | c.321G>A p.W107* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV55368332; called by muse, mutect2, varscan2
- CAMTA1 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57910674; called by muse, mutect2, varscan2
- CBLIF | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773758355, COSV57238729, COSV57239513; called by muse, mutect2, varscan2
- CC2D2B | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV60358405; called by muse, mutect2, varscan2
- CCDC27 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV53901492; called by muse, mutect2, varscan2
- CD84 | c.761G>A p.G254D (on ENST00000311224 / NM_001184879.2; = p.X254_splice on NM_003874.4) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV60869219; called by muse, mutect2, varscan2
- CDC42BPG | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1280017674, COSV61348139; called by muse, mutect2, varscan2
- CDH17 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs1380771629, COSV50332029, COSV50340574; called by muse, mutect2, varscan2
- CDH4 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs368305378; called by muse, mutect2, varscan2
- CEACAM6 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.351); catalogued as COSV52269203; called by muse, mutect2, varscan2
- CEP192 | c.3715G>A p.D1239N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV58066827; called by muse, mutect2, varscan2
- CEP63 | c.1161A>C p.E387D | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV59677345; called by muse, mutect2, varscan2
- CFAP47 | c.5062G>A p.E1688K | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs781508080, COSV100544864, COSV57974966; called by muse, mutect2, varscan2
- CFAP57 | c.1909C>T p.H637Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV65264827; called by muse, mutect2, varscan2
- CHIA | c.437G>A p.G146E (on ENST00000343320; = p.G38E on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58476504; called by muse, mutect2, varscan2
- CHST14 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV60379096; called by muse, mutect2, varscan2
- CHSY1 | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54254496; called by muse, mutect2, varscan2
- CIART | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.848); catalogued as rs868913120, COSV51744901; called by muse, mutect2, varscan2
- CIB4 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs201259271; called by muse, mutect2, varscan2
- CLASP2 | c.2277T>G p.S759R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56286410; called by muse, mutect2, varscan2
- CLEC18B | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1244361176, COSV60578067; called by muse, mutect2, varscan2
- CNGA3 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV55624555; called by muse, mutect2, varscan2
- CNTNAP2 | c.2063A>C p.Y688S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62211010; called by muse, mutect2, varscan2
- CNTNAP5 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV70494470, COSV70520200; called by muse, mutect2, varscan2
- COL11A2 | c.2179G>A p.G727R (on ENST00000341947 / NM_080680.3; = p.G620R on NM_080679.2) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768569721, COSV59498921; called by muse, mutect2, varscan2
- COL19A1 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.659); catalogued as COSV59577870; called by muse, mutect2, varscan2
- COL6A2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.771); catalogued as rs932129947, COSV56009749; called by muse, mutect2, varscan2
- COL6A3 | c.9250C>T p.P3084S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1468004640, COSV55096450; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPA2 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55980399; called by muse, mutect2
- CPZ | c.1370C>T p.S457F (on ENST00000360986 / NM_001014447.3; = p.S446F on NM_003652.3) | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV59924031; called by muse, mutect2, varscan2
- CRTAM | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57069232; called by muse, mutect2, varscan2
- CSMD1 | c.8144G>A p.G2715E (on ENST00000520002; = p.G2714E on NM_033225.6) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59315114; called by muse, mutect2, varscan2
- CSMD1 | c.3658G>A p.D1220N (on ENST00000520002; = p.D1219N on NM_033225.6) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1238588602, COSV59324607, COSV59333849; called by muse, mutect2
- CSMD3 | c.8897G>A p.G2966E (on ENST00000297405 / NM_001363185.1; = p.G2797E on NM_052900.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52230702; called by muse, varscan2
- CSTF3 | c.885T>G p.Y295* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV60612553; called by muse, mutect2, varscan2
- CTCFL | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs188483123, COSV54776247; called by muse, mutect2, varscan2
- CUL9 | c.2008G>A p.G670S | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT tolerated (0.38); PolyPhen benign (0.188); catalogued as COSV52730806; called by muse, mutect2, varscan2
- DBF4 | c.506T>G p.I169S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55997694, COSV55998319; called by muse, mutect2, varscan2
- DCC | c.3061C>T p.R1021* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV59103256; called by muse, mutect2, varscan2
- DENND4A | c.4552C>T p.P1518S | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV71266436; called by muse, mutect2, varscan2
- DMRTA1 | c.1004A>T p.K335M | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57924642; called by muse, mutect2, varscan2
- DNAH10 | c.4639T>C p.Y1547H (on ENST00000409039; = p.Y1486H on NM_207437.3) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV68996443; called by muse, mutect2, varscan2
- DNAH10 | c.7273G>A p.E2425K (on ENST00000409039; = p.E2364K on NM_207437.3) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs772186721, COSV68996448; called by muse, mutect2, varscan2
- DNAH7 | c.5591A>T p.D1864V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV56772739; called by muse, mutect2, varscan2
- DNAH8 | c.4808C>T p.T1603I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59429673; called by muse, mutect2, varscan2
- DNAH8 | c.7645G>T p.E2549* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as COSV59460409; called by muse, mutect2
- DNAH9 | c.3594G>A p.W1198* | Nonsense Mutation (SNP) | VAF 29/31 reads (94%) | catalogued as rs747252427, COSV52358768; called by muse, mutect2, varscan2
- DPPA2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs922189877, COSV72118023; called by muse, mutect2, varscan2
- DPRX | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV64949752; called by muse, mutect2, varscan2
- DPYD | c.2893G>A p.D965N | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929332, COSV64604341; called by muse, mutect2, varscan2
- DPYD | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.798); catalogued as rs267598785, COSV64591183; called by muse, mutect2, varscan2
- DSCAML1 | c.2026C>T p.P676S (on ENST00000321322; = p.P616S on NM_020693.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV58402237; called by muse, mutect2, varscan2
- DSG1 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs1030342250, COSV57136999; called by muse, mutect2, varscan2
- DSG4 | c.1933T>C p.L645= | Splice Region (SNP) | VAF 36/54 reads (67%) | catalogued as COSV57393679; called by muse, mutect2, varscan2
- DYNC2I1 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.235); catalogued as rs892415238, COSV68105663; called by muse, mutect2, varscan2
- DZIP1 | c.2242G>A p.E748K (on ENST00000347108; = p.E729K on NM_014934.5) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.074); catalogued as COSV61267160; called by muse, mutect2, varscan2
- ECI2 | c.1135G>T p.E379* (on ENST00000380118 / NM_206836.3; = p.E349* on NM_006117.2) | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | catalogued as COSV60987443; called by muse, mutect2, varscan2
- ECSCR | c.178G>C p.A60P | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV72928868; called by muse, mutect2
- EFHC1 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs746965960, COSV64136881; called by muse, mutect2, varscan2
- EFNA5 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs377722066, COSV60953440; called by muse, mutect2, varscan2
- EGFR | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); catalogued as COSV51817262; called by muse, mutect2
- FAM135B | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52736573; called by muse, mutect2, varscan2
- FAM135B | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV52709845, COSV99421515; called by muse, mutect2, varscan2
- FAT2 | c.4144T>C p.F1382L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55823626; called by muse, mutect2, varscan2
- FBF1 | c.1568C>T p.A523V (on ENST00000586717; = p.A537V on NM_001319193.1) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as COSV59865826; called by muse, mutect2, varscan2
- FBXL16 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as rs1274304987, COSV60963818; called by muse, varscan2
- FBXL16 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV60964957; called by muse, varscan2
- FBXL2 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV52136686, COSV52140272; called by muse, mutect2, varscan2
- FGD6 | c.2908A>T p.I970F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59694632; called by muse, mutect2, varscan2
- FILIP1 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 98/137 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs776455963, COSV52725973; called by muse, mutect2, varscan2
- FLG | c.6694G>T p.G2232W | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs143075913; called by muse, mutect2, varscan2
- FMNL2 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV56498446; called by muse, mutect2, varscan2
- FUT9 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56142765; called by muse, mutect2, varscan2
- FZR1 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58050243; called by muse, mutect2, varscan2
- GABRG3 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.219); catalogued as rs1337737440, COSV61519065, COSV61523357; called by muse, mutect2, varscan2
- GFM2 | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs1202152287; called by muse, mutect2, varscan2
- GK2 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs267600273, COSV62626353; called by muse, mutect2, varscan2
- GLRA1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV51018330; called by muse, mutect2, varscan2
- GLT6D1 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV65628015; called by muse, mutect2, varscan2
- GPR156 | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100251346; called by muse, mutect2, varscan2
- GPR83 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV54717775; called by muse, mutect2, varscan2
- GRIK1 | c.2297A>G p.N766S | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375794566, COSV58709453; called by muse, mutect2, varscan2
- GSPT2 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV61214647; called by muse, mutect2, varscan2
- GUCY1A2 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56492186; called by muse, mutect2, varscan2
- HCK | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52941810; called by muse, mutect2, varscan2
- HDC | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as rs368925670; called by muse, mutect2, varscan2
- HEATR5B | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.09); catalogued as rs532790945, COSV51855011; called by muse, mutect2, varscan2
- HECW1 | c.3050G>A p.R1017Q | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761103115, COSV67823072; called by muse, mutect2, varscan2
- HFE | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV58513498; called by muse, mutect2, varscan2
- HIP1 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as rs184989138, COSV61188161; called by muse, mutect2, varscan2
- HS3ST3A1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52376700; called by muse, mutect2, varscan2
- HSD3B1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 109/162 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as COSV52491326; called by muse, mutect2, varscan2
- IGHMBP2 | c.2089C>G p.P697A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54823831; called by muse, mutect2
- IL11RA | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV52405265; called by muse, mutect2, varscan2
- IL37 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54490299; called by muse, mutect2, varscan2
- IL6ST | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61140498, COSV61141939; called by muse, mutect2, varscan2
- ITGA10 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV65198070; called by muse, mutect2, varscan2
- ITGB4 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52321836; called by muse, mutect2, varscan2
- KCNB1 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100870493; called by muse, mutect2, varscan2
- KCNC1 | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56395836; called by muse, mutect2, varscan2
- KCTD13 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV58160450; called by muse, mutect2, varscan2
- KLHL18 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51746891; called by muse, mutect2, varscan2
- KLK4 | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 117/236 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV60676625; called by muse, mutect2, varscan2
- KRT26 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as rs765589041; called by muse, mutect2, varscan2
- KRTAP5-10 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1450707093, COSV64794084; called by muse, varscan2
- LAMB3 | c.3304G>T p.G1102C | Missense Mutation (SNP) | VAF 84/141 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV50520183, COSV50523384; called by muse, mutect2, varscan2
- LCE1B | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 39/52 reads (75%) | catalogued as COSV100780271, COSV63980247; called by muse, mutect2, varscan2
- LCP2 | c.345T>G p.S115R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV50454663; called by muse, mutect2, varscan2
- LDHAL6A | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55008238; called by muse, mutect2, varscan2
- LGI2 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 105/143 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV66122359; called by muse, mutect2, varscan2
- LRP1B | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1379294814, COSV67196367; called by muse, mutect2, varscan2
- LRRC47 | c.719A>C p.K240T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV65562871; called by muse, mutect2, varscan2
- LRRFIP1 | c.1126C>T p.L376F (on ENST00000392000 / NM_001137552.2; = p.L352F on NM_004735.4) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.735); catalogued as COSV55253475; called by muse, mutect2, varscan2
- LYN | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV70205371, COSV70205986; called by muse, mutect2, varscan2
- MARF1 | c.3856C>T p.P1286S | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60025545; called by muse, mutect2, varscan2
- MARK4 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.183); catalogued as rs756211354, COSV53462314, COSV53465645; called by muse, mutect2, varscan2
- MED12 | c.5314C>T p.P1772S | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100380166, COSV61345551; called by mutect2, varscan2
- MED13 | c.5959C>T p.P1987S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV67264969; called by muse, mutect2, varscan2
- METTL25 | c.1262T>A p.F421Y | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV50257434; called by muse, varscan2
- MGA | c.7186C>T p.R2396* (on ENST00000219905 / NM_001164273.1; = p.R2187* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as COSV54949891; called by muse, mutect2, varscan2
- MGAM | c.3444G>A p.W1148* | Nonsense Mutation (SNP) | VAF 67/91 reads (74%) | catalogued as COSV72075012; called by muse, mutect2, varscan2
- MICAL2 | c.4276G>A p.E1426K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.062); catalogued as rs868131106, COSV56287132; called by muse, mutect2, varscan2
- MPO | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs147998181, COSV56565627; called by muse, mutect2, varscan2
- MROH7 | c.3849G>A p.W1283* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100988544, COSV64887705; called by muse, mutect2, varscan2
- MUC16 | c.23960C>T p.S7987F | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.857); catalogued as COSV67477169; called by muse, mutect2, varscan2
- MUC16 | c.23047G>A p.E7683K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.047); catalogued as COSV67477173, COSV67492246; called by muse, mutect2, varscan2
- MXRA5 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 109/130 reads (84%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as rs770515977, COSV54240827; called by muse, mutect2, varscan2
- MYH13 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs201107300, COSV52820473, COSV52827079; called by muse, mutect2, varscan2
- MYO1C | c.416C>A p.S139Y (on ENST00000648651 / NM_001080779.2; = p.S104Y on NM_033375.5) | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62999899; called by muse, mutect2, varscan2
- MYOZ1 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV63772210; called by muse, mutect2, varscan2
- MYPN | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV62735394; called by muse, mutect2, varscan2
- NARS2 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0.137); catalogued as COSV55253293; called by muse, mutect2
- NBR1 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57833658; called by muse, mutect2, varscan2
- NCOA2 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774406485, COSV71764281; called by muse, mutect2, varscan2
- NCR1 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52556034; called by muse, mutect2, varscan2
- NEBL | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV65801669; called by muse, mutect2, varscan2
- NIBAN1 | c.1081G>C p.G361R | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62286007, COSV62287400; called by muse, mutect2
- NLN | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV66766360; called by muse, mutect2, varscan2
- NLRP2 | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV54756977; called by muse, mutect2, varscan2
- NLRP8 | c.2001G>A p.M667I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs750251350, COSV52590122; called by muse, mutect2, varscan2
- NMI | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV54638522; called by muse, mutect2, varscan2
- NOD1 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56113480; called by muse, mutect2, varscan2
- NOSTRIN | c.1452dup p.G485Rfs*57 (on ENST00000317647 / NM_001039724.4; = p.G407Rfs*? on NM_052946.3) | Frame Shift Ins (INS) | VAF 26/64 reads (41%) | catalogued as rs757832201; called by mutect2, pindel, varscan2
- NPVF | c.208G>C p.V70L | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as COSV99760252; called by mutect2, varscan2
- NTRK1 | c.1979A>T p.Q660L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV62326653; called by muse, mutect2, varscan2
- OR2D3 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs146157596, COSV53494850; called by muse, mutect2, varscan2
- OR2M5 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.516); catalogued as COSV63546591; called by muse, mutect2, varscan2
- OR51Q1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs868427881, COSV56179758; called by muse, mutect2, varscan2
- OR5B21 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64482074; called by muse, mutect2, varscan2
- OR6C70 | c.695A>T p.K232M | Missense Mutation (SNP) | VAF 71/94 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV59245030; called by muse, mutect2, varscan2
- OR6N1 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV58649292; called by muse, mutect2, varscan2
- OR8K1 | c.188C>A p.T63N | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); catalogued as COSV54403307; called by muse, mutect2, varscan2
- PAK1 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53698197; called by muse, mutect2, varscan2
- PAMR1 | c.1421G>A p.G474E (on ENST00000619888 / NM_001001991.3; = p.G491E on NM_015430.4) | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.691); catalogued as COSV53513907; called by muse, mutect2, varscan2
- PARP15 | c.1135C>T p.P379S (on ENST00000464300 / NM_001113523.3; = p.P145S on NM_152615.2) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV59973440; called by muse, mutect2, varscan2
- PATE1 | c.196A>T p.I66L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs149639744, COSV59824862; called by muse, mutect2, varscan2
- PAX4 | c.431C>A p.S144* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV58389697; called by muse, varscan2
- PAXIP1 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867599064, COSV68186663; called by muse, mutect2, varscan2
- PCDH18 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 39/59 reads (66%) | catalogued as rs766574471, COSV61269770; called by muse, mutect2, varscan2
- PCDH8 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58813732; called by muse, mutect2, varscan2
- PCDH9 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV60556469, COSV60565772; called by muse, mutect2, varscan2
- PCDHA6 | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as rs782178677, COSV65345296; called by muse, mutect2, varscan2
- PCDHA7 | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.968); catalogued as COSV65345305; called by muse, mutect2, varscan2
- PCDHAC1 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs781843995, COSV53836291; called by muse, mutect2, varscan2
- PCDHB2 | c.302C>A p.T101K | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as COSV52034400; called by muse, mutect2, varscan2
- PCDHGA2 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53902099; called by muse, mutect2, varscan2
- PCDHGA9 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.035); catalogued as COSV53978976, COSV54000796; called by muse, mutect2, varscan2
- PCSK5 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65091890; called by muse, mutect2
- PDE1C | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.7); catalogued as rs866066614, COSV68810509; called by muse, mutect2, varscan2
- PDE8B | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs1348198236, COSV53740309; called by muse, mutect2, varscan2
- PDLIM1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV61474389; called by muse, mutect2, varscan2
- PDZD4 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV51246926; called by muse, mutect2, varscan2
- PGAM5 | c.596A>G p.E199G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs374693479; called by muse, mutect2, varscan2
- PGAP4 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66387982; called by muse, mutect2, varscan2
- PHKA1 | c.2137+1G>A p.X713_splice | Splice Site (SNP) | VAF 6/10 reads (60%) | catalogued as rs989735986, COSV59807849; called by muse, mutect2, varscan2
- PIGO | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.477); catalogued as COSV53054251; called by muse, mutect2, varscan2
- PKHD1L1 | c.12328G>A p.D4110N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.111); catalogued as COSV65746770; called by mutect2, varscan2
- PLCB4 | c.369+1G>A p.X123_splice | Splice Site (SNP) | VAF 14/20 reads (70%) | catalogued as COSV99595762; called by muse, mutect2, varscan2
- PLD1 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV60570131; called by muse, mutect2, varscan2
- PLEC | c.2324A>T p.E775V (on ENST00000322810 / NM_201380.4; = p.E665V on NM_000445.5) | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59656257; called by mutect2, varscan2
- PLIN3 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV55735919; called by muse, mutect2, varscan2
- POF1B | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV53136481; called by muse, mutect2, varscan2
- POU2AF1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV67577435; called by muse, mutect2, varscan2
- PPARGC1A | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.69); PolyPhen benign (0.272); catalogued as COSV53529897; called by muse, mutect2, varscan2
- PRRC2C | c.7402C>T p.P2468S (on ENST00000367742; = p.P2466S on NM_015172.4) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as rs1257009861, COSV58907999; called by muse, mutect2, varscan2
- PTEN | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV64288425, COSV64299515; called by muse, mutect2, varscan2
- PTPN9 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60724570; called by muse, mutect2, varscan2
- PTPRB | c.4678G>A p.D1560N | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs778294640, COSV54241229; called by muse, mutect2, varscan2
- PTPRH | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.043); catalogued as COSV54744709; called by muse, mutect2, varscan2
- PTX3 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV55821580; called by muse, mutect2, varscan2
- RABEP1 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776939752, COSV52586199; called by muse, mutect2, varscan2
- RAD51AP2 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV67588482; called by muse, mutect2, varscan2
- RAF1 | c.50T>C p.F17S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); catalogued as rs1454494958, COSV52580421; called by muse, mutect2, varscan2
- RASAL1 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs149283617, COSV55654342; called by muse, mutect2, varscan2
- RAVER2 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs774986737, COSV53808601; called by muse, mutect2, varscan2
- RBM46 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867870643, COSV55980139; called by muse, mutect2, varscan2
- RELN | c.9211G>A p.E3071K | Missense Mutation (SNP) | VAF 79/87 reads (91%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.854); catalogued as COSV59014413; called by muse, mutect2, varscan2
- RERE | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 78/143 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV61945095; called by muse, mutect2, varscan2
- RIMS4 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV65719085; called by muse, mutect2, varscan2
- RP1 | c.3859G>T p.G1287C | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV55120429; called by muse, mutect2, varscan2
- RTN3 | c.947C>T p.S316L (on ENST00000377819 / NM_001265589.2; = p.S297L on NM_201428.3) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs771946088, COSV58029979; called by muse, mutect2, varscan2
- SAMD9 | c.4270C>A p.L1424M | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV66076423; called by muse, mutect2
- SCN1A | c.3331C>T p.L1111F (on ENST00000303395 / NM_001202435.3; = p.L1100F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV57676355; called by muse, mutect2, varscan2
- SCN5A | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV61130453, COSV61132420; called by muse, mutect2, varscan2
- SCN7A | c.1207A>G p.R403G | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV69272800; called by muse, mutect2, varscan2
- SCN7A | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1334859835, COSV69272802; called by muse, mutect2, varscan2
- SCN9A | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202083986, COSV57599428; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SELP | c.1951G>A p.G651R | Missense Mutation (SNP) | VAF 119/194 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55254354; called by muse, mutect2, varscan2
- SEMA6C | c.673C>A p.H225N | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV59004886; called by muse, mutect2, varscan2
- SENP7 | c.2470C>T p.P824S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.488); catalogued as COSV58614382; called by muse, mutect2
- SERPINB3 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as rs865911012, COSV52192601; called by muse, mutect2, varscan2
- SESN2 | c.629T>G p.F210C | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53427607; called by muse, mutect2, varscan2
- SFRP4 | c.525C>T p.P175= | Splice Region (SNP) | VAF 39/102 reads (38%) | catalogued as rs546060485; called by muse, mutect2, varscan2
- SFRP4 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1187904199, COSV71412690; called by muse, mutect2, varscan2
- SH2B3 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs776733533, COSV57984519; called by muse, mutect2, varscan2
- SH3RF1 | c.2188C>T p.R730W | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs929682766, COSV52919682; called by muse, mutect2, varscan2
- SIRPG | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV53808475; called by muse, mutect2, varscan2
- SLC12A8 | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs765064853, COSV58867765; called by muse, mutect2, varscan2
- SLC17A6 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV54138183; called by muse, mutect2, varscan2
- SLC1A6 | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV55671791; called by muse, mutect2, varscan2
- SLC22A11 | c.393G>A p.K131= | Splice Region (SNP) | VAF 5/14 reads (36%) | catalogued as COSV57253952; called by muse, mutect2, varscan2
- SLC22A23 | c.1313C>A p.S438* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as COSV66676679, COSV66678228; called by muse, mutect2, varscan2
- SLC22A8 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV60325868; called by muse, mutect2, varscan2
- SLC44A5 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 72/279 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV63768460; called by muse, mutect2, varscan2
- SLC7A14 | c.1316G>A p.G439D | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV51585188; called by muse, mutect2, varscan2
- SLCO2B1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs865987804, COSV56936636; called by muse, mutect2, varscan2
- SLIT1 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56592858, COSV99821826; called by muse, mutect2, varscan2
- SMARCC1 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as COSV54383030, COSV54387771; called by muse, mutect2, varscan2
- SPATA21 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV59187648; called by muse, mutect2
- SPNS3 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV61070770, COSV61070797; called by muse, varscan2
- SRBD1 | c.1115T>C p.I372T | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV55401221; called by muse, varscan2
- SYT9 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV59621137; called by muse, mutect2, varscan2
- TACR1 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV59483393; called by muse, mutect2, varscan2
- TAF1 | c.2443C>T p.P815S (on ENST00000373790 / NM_138923.4; = p.P836S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52117834; called by muse, mutect2, varscan2
- TAF1L | c.2628G>A p.M876I | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV54258962; called by muse, mutect2, varscan2
- TBATA | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 25/37 reads (68%) | catalogued as COSV54719915; called by muse, mutect2, varscan2
- TBPL2 | c.1080A>T p.E360D | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs757244526, COSV55957118; called by muse, varscan2
- THADA | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 115/263 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as COSV57681646; called by muse, mutect2, varscan2
- TMED5 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as COSV64757213; called by muse, mutect2, varscan2
- TMEM132D | c.919T>A p.F307I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as COSV70611803; called by muse, mutect2, varscan2
- TMEM176B | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 106/137 reads (77%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs750751165, COSV58440244; called by muse, varscan2
- TMEM184A | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV52474357; called by muse, mutect2, varscan2
- TMEM260 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV104375029, COSV55100738; called by muse, mutect2, varscan2
- TNFRSF8 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as rs1410281984, COSV55797954; called by muse, mutect2, varscan2
- TOPBP1 | c.2709G>C p.K903N | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV53438081; called by muse, mutect2, varscan2
- TRANK1 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs369479012; called by muse, varscan2
- TRPM1 | c.907A>G p.N303D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs767092004, COSV56637361; called by muse, mutect2, varscan2
- TSPAN9 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as rs774632414, COSV50722240; called by muse, mutect2, varscan2
- TTC13 | c.1751G>C p.W584S | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64169007; called by muse, mutect2, varscan2
- TTC21B | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 43/128 reads (34%) | catalogued as rs771232897, COSV54630735; called by muse, mutect2, varscan2
- TTN | c.98305G>A p.E32769K (on ENST00000591111; = p.E25345K on NM_003319.4) | Missense Mutation (SNP) | VAF 41/94 reads (44%) | PolyPhen benign (0.311); catalogued as COSV60168668; called by muse, mutect2, varscan2
- TTN | c.77308G>A p.E25770K (on ENST00000591111; = p.E18346K on NM_003319.4) | Missense Mutation (SNP) | VAF 50/114 reads (44%) | PolyPhen benign (0.043); catalogued as COSV60034178; called by muse, mutect2, varscan2
- TTN | c.60684G>A p.M20228I (on ENST00000591111; = p.M12804I on NM_003319.4) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | PolyPhen benign (0.077); catalogued as rs960935807, COSV60168716; called by muse, mutect2, varscan2
- TTN | c.45651C>A p.D15217E (on ENST00000591111; = p.D7793E on NM_003319.4) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | PolyPhen benign (0.003); catalogued as COSV60168733; called by muse, mutect2, varscan2
- TTN | c.21371G>A p.R7124Q (on ENST00000591111; = p.R6197Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/132 reads (36%) | PolyPhen possibly damaging (0.846); catalogued as rs774382033, COSV60168781; called by muse, mutect2, varscan2
- TTN | c.3331C>T p.P1111S (on ENST00000591111; = p.P1065S on NM_003319.4) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | PolyPhen probably damaging (0.998); catalogued as rs727504210, COSV60168790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBL7 | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV100795374, COSV63706393; called by muse, mutect2, varscan2
- UGT1A6 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 133/307 reads (43%) | catalogued as COSV59392476; called by muse, mutect2, varscan2
- UGT1A9 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 95/251 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375970481; called by muse, mutect2, varscan2
- USH2A | c.6527A>G p.Y2176C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1215696030, COSV56393668; called by muse, mutect2
- VCAN | c.6934G>A p.G2312R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs794727913, COSV54109192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VMO1 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV54497233; called by muse, mutect2
- VPS52 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV71403384, COSV71403453; called by muse, mutect2
- WBP2NL | c.490T>G p.C164G | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1181178579; called by muse, mutect2, varscan2
- WDFY3 | c.6760C>T p.H2254Y | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55706179; called by muse, varscan2
- WDR48 | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs780784650, COSV56532792; called by muse, mutect2, varscan2
- WDR62 | c.3146C>T p.S1049F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54336716; called by muse, mutect2, varscan2
- WDR72 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV64748640; called by muse, mutect2, varscan2
- XIRP2 | c.5120G>A p.W1707* (on ENST00000628543; = p.W1882* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV54696186; called by muse, mutect2, varscan2
- XIRP2 | c.7043C>T p.S2348L (on ENST00000628543; = p.S2523L on NM_152381.6) | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1456895639, COSV54712922; called by muse, mutect2, varscan2
- XIRP2 | c.9370G>A p.V3124I (on ENST00000628543; = p.V3299I on NM_152381.6) | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.936); catalogued as COSV54712933; called by muse, mutect2, varscan2
- YLPM1 | c.4262C>T p.P1421L | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV53115353; called by muse, mutect2, varscan2
- ZAN | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV61811254; called by muse, mutect2, varscan2
- ZBTB40 | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289100794, COSV65145784; called by muse, mutect2, varscan2
- ZCCHC8 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV60317532; called by muse, mutect2, varscan2
- ZIC1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1461615959, COSV51555489; called by muse, mutect2, varscan2
- ZMAT4 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs867752388, COSV52704877; called by muse, mutect2, varscan2
- ZNF211 | c.962C>T p.S321L (on ENST00000347302 / NM_198855.4; = p.S334L on NM_006385.5) | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs753395520, COSV53742804; called by muse, mutect2, varscan2
- ZNF227 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs766499481, COSV57312922; called by muse, varscan2
- ZNF329 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV63772037; called by muse, mutect2, varscan2
- ZNF407 | c.3980C>T p.S1327F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs1267662357, COSV55250353; called by muse, mutect2, varscan2
- ZNF418 | c.1642C>T p.H548Y | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as COSV68676110; called by muse, mutect2, varscan2
- ZNF528 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as COSV64620117; called by muse, mutect2, varscan2
- ZNF573 | c.704A>C p.Q235P (on ENST00000536220 / NM_001172692.1; = p.Q177P on NM_152360.3) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.602); catalogued as COSV59826515; called by muse, mutect2, varscan2
- ZNF667 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV52632721; called by muse, mutect2, varscan2
- ZNF671 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58053422; called by muse, mutect2, varscan2
- ZNF804A | c.219C>G p.D73E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56456700; called by muse, mutect2, varscan2
- ZNF804A | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56456709; called by muse, mutect2, varscan2
- ZNF831 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1312023990, COSV64037996; called by muse, mutect2, varscan2
- ZNF831 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV64042114; called by muse, mutect2, varscan2
- ZSCAN5A | c.836G>C p.R279T | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54228511; called by muse, mutect2, varscan2
- ZSWIM3 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs542143044, COSV54849048; called by muse, mutect2, varscan2
- ZSWIM5 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415120479, COSV62735258; called by muse, mutect2, varscan2
- ZYX | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV59556864; called by muse, mutect2, varscan2
- CALCA | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CALCA | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CIB4 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 67/216 reads (31%) | called by muse, mutect2, varscan2
- CROCC | c.4586G>C p.R1529P | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- GFM2 | c.1313T>A p.L438H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR156 | c.162G>A p.W54* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- IGHV3-66 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- IGKV1D-42 | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by mutect2, varscan2
- JAK2 | c.1729_1730del p.E577Sfs*8 | Frame Shift Del (DEL) | VAF 10/19 reads (53%) | called by mutect2, pindel, varscan2
- KLHL3 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- MAPK9 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- NEK8 | c.1543del p.Q515Kfs*3 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel*, varscan2
- PLCB4 | c.369G>A p.K123= | Splice Region (SNP) | VAF 15/21 reads (71%) | called by muse, mutect2, varscan2
- PNPLA6 | c.1382C>T p.P461L (on ENST00000414982 / NM_001166111.2; = p.P413L on NM_006702.5) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- PRKX | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 67/88 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SAMD9 | c.4463G>A p.R1488K | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMD9 | c.4462A>T p.R1488* | Nonsense Mutation (SNP) | VAF 35/44 reads (80%) | called by muse, mutect2, varscan2
- TAS2R4 | c.226del p.R76Gfs*24 | Frame Shift Del (DEL) | VAF 52/296 reads (18%) | called by mutect2, pindel, varscan2
- WBP2NL | c.491G>T p.C164F | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ZNF490 | c.851del p.G284Efs*11 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- ZNF683 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF71 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ZNF71 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ACD | c.129G>A p.R43= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.2244G>A p.L748= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV54356427; called by muse, mutect2, varscan2
- ADAMTS18 | c.732C>T p.H244= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs748358878, COSV51418449; called by muse, mutect2, varscan2
- ANGPT1 | c.663C>T p.G221= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV52446296, COSV52458589; called by muse, mutect2, varscan2
- ANKRD30A | c.3165C>T p.I1055= (on ENST00000611781; = p.I999= on NM_052997.2) | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as rs369533113, COSV64616750; called by muse, mutect2, varscan2
- ANKRD45 | c.687G>A p.L229= | Silent (SNP) | VAF 30/44 reads (68%) | catalogued as rs1429071959, COSV100322460, COSV60961690; called by muse, mutect2, varscan2
- ARID1B | c.2865C>T p.N955= | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as COSV51668770; called by muse, mutect2, varscan2
- ARMC9 | c.1812C>T p.D604= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs199727070, COSV100589767, COSV63020146; called by muse, mutect2, varscan2
- ARSJ | c.852C>T p.S284= | Silent (SNP) | VAF 46/64 reads (72%) | catalogued as COSV59538561; called by muse, mutect2, varscan2
- ASPM | c.6924C>T p.F2308= | Silent (SNP) | VAF 49/83 reads (59%) | catalogued as COSV54132973; called by muse, varscan2
- ATRX | c.2604G>A p.L868= | Silent (SNP) | VAF 51/178 reads (29%) | catalogued as COSV64879171; called by muse, mutect2, varscan2
- BAZ2B | c.3756C>T p.L1252= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV54276115; called by muse, mutect2, varscan2
- BRINP2 | c.1956C>T p.S652= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as COSV64178518; called by muse, mutect2, varscan2
- C1orf116 | c.297G>A p.E99= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV63944308; called by muse, mutect2, varscan2
- CACNA1E | c.6684C>T p.I2228= (on ENST00000367573 / NM_001205293.3; = p.I2185= on NM_000721.4) | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV62403534; called by muse, mutect2, varscan2
- CATSPER2 | c.1426C>T p.L476= (on ENST00000321596 / NM_001282309.3; = p.L478= on NM_172095.4) | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV58661245; called by muse, mutect2, varscan2
- CATSPERD | c.2337G>A p.R779= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1347786034, COSV58466068; called by muse, varscan2
- CCDC158 | c.3117T>C p.Y1039= | Silent (SNP) | VAF 61/85 reads (72%) | catalogued as COSV66356554; called by muse, mutect2, varscan2
- CCDC69 | c.706C>T p.L236= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV62600117; called by muse, mutect2, varscan2
- CCT8L2 | c.138C>T p.V46= | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as COSV63462640; called by muse, mutect2, varscan2
- CD163L1 | c.3612C>T p.F1204= | Silent (SNP) | VAF 43/58 reads (74%) | catalogued as rs767456913, COSV58019256; called by muse, mutect2, varscan2
- CDH13 | c.1665C>T p.F555= | Silent (SNP) | VAF 74/179 reads (41%) | catalogued as COSV51838665; called by muse, mutect2, varscan2
- CDH7 | c.423C>A p.I141= | Silent (SNP) | VAF 44/79 reads (56%) | catalogued as COSV59888833, COSV59893795; called by muse, mutect2, varscan2
- CEACAM6 | c.621G>A p.R207= | Silent (SNP) | VAF 52/116 reads (45%) | called by muse, mutect2, varscan2
- CEP350 | c.7581C>T p.A2527= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs781220580, COSV62605247; called by muse, mutect2, varscan2
- CHST14 | c.1068C>T p.I356= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV60378460; called by muse, mutect2, varscan2
- CIBAR2 | c.405A>C p.S135= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV73320644; called by muse, mutect2, varscan2
- CNIH2 | c.303C>T p.H101= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV61012703; called by muse, mutect2, varscan2
- CNTF | c.573C>T p.S191= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs1222627017, COSV60160282; called by muse, mutect2, varscan2
- CNTN6 | c.1068A>G p.E356= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV63174501, COSV63178303; called by muse, mutect2, varscan2
- CPZ | c.186C>A p.P62= (on ENST00000360986 / NM_001014447.3; = p.P51= on NM_003652.3) | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as COSV59924022; called by muse, mutect2, varscan2
- CR2 | c.307A>C p.R103= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as COSV65508481; called by muse, mutect2, varscan2
- CRNKL1 | c.336G>A p.A112= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as rs867115962, COSV55636261, COSV99846278, COSV99846944; called by muse, mutect2, varscan2
- CROCC | c.4585C>A p.R1529= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100978213; called by muse, mutect2, varscan2
- DAB2IP | c.2241C>T p.S747= (on ENST00000408936; = p.S719= on NM_032552.3) | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs1044722538, COSV52262809; called by muse, varscan2
- DDR1 | c.1020C>T p.G340= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as COSV61322406; called by muse, mutect2, varscan2
- DGKI | c.2049C>A p.P683= | Silent (SNP) | VAF 40/205 reads (20%) | catalogued as COSV55959420; called by mutect2, varscan2
- DMXL2 | c.7245C>T p.H2415= | Silent (SNP) | VAF 58/107 reads (54%) | catalogued as COSV51849878; called by muse, mutect2, varscan2
- DSP | c.5622G>A p.K1874= | Silent (SNP) | VAF 57/107 reads (53%) | catalogued as COSV65793803; called by muse, mutect2, varscan2
- DYDC2 | c.312C>T p.F104= | Silent (SNP) | VAF 68/88 reads (77%) | catalogued as COSV55472735; called by muse, mutect2, varscan2
- EML1 | c.1044C>T p.S348= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as rs767761147, COSV51742327; called by muse, mutect2, varscan2
- EPHB3 | c.261C>T p.S87= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV57807286; called by muse, mutect2, varscan2
- F5 | c.3549G>A p.Q1183= | Silent (SNP) | VAF 95/164 reads (58%) | catalogued as COSV63125676; called by muse, mutect2, varscan2
- FBF1 | c.2208C>T p.S736= (on ENST00000586717; = p.S750= on NM_001319193.1) | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV59865820; called by muse, varscan2
- FLVCR1 | c.858A>G p.T286= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs539066879, COSV65323980; called by muse, mutect2, varscan2
- FOLR1 | c.645C>T p.D215= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV56616533; called by muse, mutect2, varscan2
- GLG1 | c.3249C>T p.T1083= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV52669845; called by muse, mutect2, varscan2
- GMDS | c.306C>T p.P102= | Silent (SNP) | VAF 123/208 reads (59%) | catalogued as COSV66437489; called by muse, mutect2, varscan2
- GMEB1 | c.1338C>T p.F446= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV53795200; called by muse, mutect2, varscan2
- GNMT | c.783C>T p.F261= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs201991849, COSV55103084; called by muse, mutect2, varscan2
- GPR158 | c.2304G>A p.Q768= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as COSV66274652; called by muse, mutect2, varscan2
- GPR39 | c.819G>A p.E273= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV61425148; called by muse, mutect2, varscan2
- HAVCR1 | c.582G>A p.T194= | Silent (SNP) | VAF 143/669 reads (21%) | catalogued as rs775670904, COSV59400386; called by muse, varscan2
- HCFC1 | c.4458C>T p.T1486= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs782395790, COSV60074455; called by muse, mutect2, varscan2
- HEPACAM | c.102G>A p.V34= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV53430930; called by muse, mutect2, varscan2
- HPN | c.513G>A p.L171= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV52884094, COSV52884507; called by muse, varscan2
- IDO2 | c.921C>T p.F307= (on ENST00000389060; = p.F320= on NM_194294.2) | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV58429893; called by muse, mutect2, varscan2
- IGHV3-64 | c.186G>A p.G62= | Silent (SNP) | VAF 70/112 reads (63%) | called by muse, mutect2, varscan2
- IGLV2-18 | c.280C>T p.L94= | Silent (SNP) | VAF 64/77 reads (83%) | called by muse, mutect2, varscan2
- ITGA7 | c.1269C>T p.S423= (on ENST00000555728; = p.S379= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV57697228; called by muse, mutect2, varscan2
- KCNB1 | c.1092C>T p.I364= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as COSV65569356; called by muse, mutect2, varscan2
- KCNS1 | c.1500C>T p.S500= | Silent (SNP) | VAF 59/179 reads (33%) | catalogued as COSV60260466; called by muse, mutect2, varscan2
- KIAA0319 | c.3025C>T p.L1009= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV65499860; called by muse, mutect2, varscan2
- KIF5C | c.1599G>A p.L533= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV68482272; called by muse, mutect2, varscan2
- KLB | c.1443G>C p.V481= | Silent (SNP) | VAF 46/56 reads (82%) | catalogued as rs745946153, COSV57302805; called by muse, mutect2, varscan2
- KRT26 | c.561G>A p.E187= | Silent (SNP) | VAF 30/45 reads (67%) | called by muse, mutect2, varscan2
- KRTAP4-5 | c.285C>T p.C95= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs1435784769, COSV58352681; called by muse, varscan2
- LAMC3 | c.2460C>T p.A820= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1055291211, COSV63092444; called by muse, mutect2, varscan2
- LGALS12 | c.90G>A p.T30= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV55370503; called by muse, mutect2, varscan2
- LILRA1 | c.1428G>A p.G476= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV52178522; called by muse, mutect2, varscan2
- LILRB5 | c.637C>T p.L213= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV60259238; called by muse, mutect2, varscan2
- LMX1B | c.366C>T p.I122= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs200350302, COSV62740594; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRSAM1 | c.2043G>A p.R681= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV55941023; called by muse, mutect2, varscan2
- MACC1 | c.2133G>A p.R711= | Silent (SNP) | VAF 53/107 reads (50%) | catalogued as COSV60544246; called by muse, mutect2, varscan2
- MICAL2 | c.3342C>T p.F1114= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as COSV56322333, COSV56325770; called by muse, mutect2, varscan2
- MOV10 | c.630C>T p.F210= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV62491865; called by muse, mutect2, varscan2
- MRGPRX2 | c.106C>T p.L36= | Silent (SNP) | VAF 68/131 reads (52%) | catalogued as COSV61674487, COSV61674652; called by muse, mutect2, varscan2
- MROH7 | c.3579A>G p.R1193= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV64887699; called by muse, mutect2
- MUC15 | c.207G>A p.A69= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as rs367651924; called by muse, mutect2, varscan2
- MUC5AC | c.162C>T p.L54= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV62254513; called by muse, mutect2, varscan2
- MYCN | c.915C>T p.N305= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs755948961, COSV55258472; called by muse, mutect2, varscan2
- MYH1 | c.1944C>T p.F648= | Silent (SNP) | VAF 64/78 reads (82%) | catalogued as COSV56851788; called by muse, mutect2, varscan2
- NDRG2 | c.921C>T p.F307= (on ENST00000298687 / NM_001354570.1; = p.F293= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 87/121 reads (72%) | catalogued as rs750913622, COSV53873039; called by muse, mutect2, varscan2
- NEB | c.13170G>A p.K4390= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV51125201, COSV51430989; called by muse, mutect2
- NFKBID | c.471C>T p.L157= (on ENST00000396901; = p.L309= on NM_032721.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs763496171, COSV61729335; called by muse, mutect2, varscan2
- NIN | c.3970C>T p.L1324= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs1383075416, COSV55396622; called by muse, mutect2, varscan2
- NLRP10 | c.1278C>T p.F426= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as rs373870786; called by muse, mutect2, varscan2
- NPC1L1 | c.915C>T p.F305= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as rs770090692, COSV56925446; called by muse, mutect2, varscan2
- NPSR1 | c.423C>T p.S141= | Silent (SNP) | VAF 92/182 reads (51%) | catalogued as COSV62203481; called by muse, mutect2, varscan2
- NPY1R | c.1095G>A p.K365= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV56715230; called by muse, mutect2, varscan2
- NRXN2 | c.4050G>A p.A1350= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs761962421, COSV55457036; called by muse, mutect2, varscan2
- NUP188 | c.1728C>T p.I576= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as COSV65363250; called by muse, varscan2
- OBSCN | c.2079C>T p.I693= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV52792083; called by muse, mutect2, varscan2
- OLFML2B | c.474C>T p.F158= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV54193778, COSV54197795; called by muse, mutect2, varscan2
- OR10G7 | c.768C>T p.F256= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs867513894, COSV57865846; called by muse, mutect2, varscan2
- OR1A1 | c.30G>A p.L10= | Silent (SNP) | VAF 52/56 reads (93%) | catalogued as COSV58404149; called by muse, mutect2, varscan2
- OR56A3 | c.933G>A p.L311= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1304950052, COSV61569530; called by muse, mutect2, varscan2
- OR5I1 | c.426C>T p.I142= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV56887825; called by muse, mutect2, varscan2
- OR5L2 | c.348C>T p.A116= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs770843874, COSV65723491; called by muse, mutect2, varscan2
- OR6C2 | c.670C>T p.L224= | Silent (SNP) | VAF 68/81 reads (84%) | catalogued as COSV59516393; called by muse, mutect2, varscan2
- OR8H2 | c.189C>T p.F63= | Silent (SNP) | VAF 47/179 reads (26%) | catalogued as COSV57944806; called by muse, mutect2, varscan2
- OTOF | c.1872G>A p.R624= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV55508427; called by muse, mutect2, varscan2
- PAH | c.240C>T p.F80= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV61017997; called by muse, mutect2, varscan2
- PCDH1 | c.3168C>T p.T1056= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs550286376; called by muse, varscan2
- PCDHAC2 | c.1608C>T p.S536= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs782537254, COSV53857573; called by muse, mutect2, varscan2
- PCDHB13 | c.2322C>T p.F774= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV53395616, COSV53399086; called by muse, mutect2, varscan2
- PCDHGA2 | c.2103C>T p.S701= | Silent (SNP) | VAF 53/115 reads (46%) | catalogued as COSV99539920; called by muse, mutect2, varscan2
- PDGFRB | c.1692C>T p.I564= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV55807158, COSV55807819; called by muse, mutect2, varscan2
- PIP5K1B | c.657G>A p.E219= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV55251737; called by muse, mutect2, varscan2
- PLD3 | c.1392C>T p.F464= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as rs1265738015, COSV52522517; called by muse, mutect2, varscan2
- POF1B | c.1677C>T p.G559= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs866057418, COSV53136462; called by muse, mutect2, varscan2
- PPHLN1 | c.342C>G p.S114= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV56733236; called by muse, mutect2, varscan2
- PRDM16 | c.921C>T p.R307= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs767412035, COSV54591403; called by muse, mutect2, varscan2
- PRKAR1B | c.978G>A p.E326= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV64319159; called by muse, mutect2, varscan2
- PRKX | c.234G>A p.K78= | Silent (SNP) | VAF 68/88 reads (77%) | called by muse, mutect2, varscan2
- PRPF31 | c.309C>T p.I103= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs369235066; called by mutect2, varscan2
- PRPS1L1 | c.105C>T p.F35= | Silent (SNP) | VAF 113/241 reads (47%) | catalogued as COSV72649935; called by muse, mutect2, varscan2
- PRUNE2 | c.7860G>A p.T2620= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV65043504; called by muse, mutect2, varscan2
- PSD4 | c.2766C>T p.S922= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as COSV55525201; called by muse, mutect2, varscan2
- PSG8 | c.306T>C p.Y102= | Silent (SNP) | VAF 107/382 reads (28%) | catalogued as rs1049355172, COSV60613245; called by muse, mutect2, varscan2
- PSMD9 | c.579C>T p.I193= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV55839976; called by muse, mutect2
- PTPRK | c.4074G>A p.V1358= (on ENST00000368215 / NM_001291984.2; = p.V1359= on NM_002844.4) | Silent (SNP) | VAF 39/63 reads (62%) | catalogued as rs1391839543, COSV63901957; called by muse, mutect2, varscan2
- RASAL1 | c.288C>G p.A96= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV55657533; called by muse, mutect2, varscan2
- RNF214 | c.1392C>T p.P464= | Silent (SNP) | VAF 36/151 reads (24%) | catalogued as COSV56119741; called by muse, mutect2, varscan2
- RP1L1 | c.6450C>T p.A2150= | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as COSV66757156; called by muse, mutect2, varscan2
- RPAP2 | c.925T>C p.L309= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV72509441; called by muse, mutect2, varscan2
- SCN11A | c.726C>T p.I242= | Silent (SNP) | VAF 30/50 reads (60%) | catalogued as rs771737794, COSV56573163; called by muse, mutect2, varscan2
- SCN2A | c.1836C>T p.F612= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs747402663, COSV51846987; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN5A | c.5373C>T p.F1791= (on ENST00000333535 / NM_198056.3; = p.F1790= on NM_000335.5) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs372380415; ClinVar: likely benign; called by mutect2, varscan2
- SERPINA9 | c.249C>T p.S83= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV54076141; called by muse, mutect2, varscan2
- SERPINB2 | c.369G>A p.L123= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV55093343; called by muse, mutect2, varscan2
- SIGLEC6 | c.1320G>A p.K440= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV58435504, COSV58435575; called by muse, mutect2, varscan2
- SLAIN1 | c.858G>A p.R286= (on ENST00000466548; = p.R23= on NM_144595.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV57387562; called by muse, mutect2, varscan2
- SLC22A14 | c.543G>A p.T181= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs769904501, COSV56198297; called by mutect2, varscan2
- SLC6A3 | c.690C>T p.I230= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs764881650, COSV54366111; called by muse, mutect2, varscan2
- SMPD3 | c.1035C>T p.F345= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs780346040, COSV54713610; called by muse, mutect2, varscan2
- SPG21 | c.522C>T p.D174= | Silent (SNP) | VAF 52/289 reads (18%) | catalogued as rs1452549947, COSV52603247; called by muse, mutect2, varscan2
- SRRM1 | c.2691G>A p.K897= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV60478693; called by muse, mutect2
- SRRM4 | c.1491G>A p.R497= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV57420262; called by muse, varscan2
- ST6GAL2 | c.720G>A p.G240= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs1456577904, COSV64529007; called by muse, mutect2, varscan2
- STRAP | c.657C>T p.S219= | Silent (SNP) | VAF 40/60 reads (67%) | catalogued as COSV50308729, COSV50309422; called by muse, mutect2, varscan2
- STRIP2 | c.1683C>T p.I561= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as rs776405776, COSV50803764; called by muse, mutect2
- SUGP2 | c.2049C>T p.L683= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV58261234; called by muse, mutect2, varscan2
- SUPT20H | c.265C>T p.L89= (on ENST00000350612 / NM_001014286.3; = p.L90= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/43 reads (88%) | catalogued as COSV62248618; called by muse, mutect2, varscan2
- TEP1 | c.3225C>T p.Y1075= | Silent (SNP) | VAF 93/119 reads (78%) | catalogued as COSV52995314; called by muse, mutect2, varscan2
- TLN2 | c.1377C>T p.G459= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV60891732; called by muse, mutect2, varscan2
- TMEM151A | c.870C>T p.L290= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs750053078, COSV59174195; called by muse, mutect2, varscan2
- TMEM176B | c.480C>T p.I160= | Silent (SNP) | VAF 92/123 reads (75%) | catalogued as rs148000953; called by muse, varscan2
- TMEM179B | c.192C>T p.Y64= | Silent (SNP) | VAF 41/73 reads (56%) | catalogued as COSV53669699; called by muse, mutect2, varscan2
- TMEM18 | c.15C>T p.F5= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV55244500, COSV99806182; called by muse, varscan2
- TMEM52 | c.624C>T p.A208= | Silent (SNP) | VAF 59/111 reads (53%) | catalogued as rs745389881, COSV57069864; called by muse, mutect2, varscan2
- TMEM82 | c.873C>T p.I291= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV65387573; called by muse, mutect2, varscan2
- TNFSF8 | c.549G>A p.T183= | Silent (SNP) | VAF 57/110 reads (52%) | catalogued as rs373154083; called by muse, mutect2, varscan2
- TPST1 | c.768C>T p.F256= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as COSV59178342; called by muse, mutect2, varscan2
- TRIM11 | c.663G>A p.Q221= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV52858673; called by muse, mutect2, varscan2
- TRPC4 | c.964A>C p.R322= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV59006179; called by muse, varscan2
- TTN | c.78090G>A p.E26030= (on ENST00000591111; = p.E18606= on NM_003319.4) | Silent (SNP) | VAF 100/214 reads (47%) | catalogued as COSV59887193, COSV59903111; called by muse, mutect2, varscan2
- TTN | c.38247C>T p.F12749= (on ENST00000591111; = p.F5325= on NM_003319.4) | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as rs776508398, COSV60168755; ClinVar: likely benign; called by muse, mutect2, varscan2
- UNC5C | c.1587C>T p.S529= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as rs745400066, COSV71658679; called by muse, mutect2, varscan2
- UROD | c.186T>G p.P62= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as COSV55801041; called by muse, mutect2, varscan2
- USH2A | c.4449C>T p.I1483= | Silent (SNP) | VAF 25/36 reads (69%) | catalogued as rs866898065, COSV56393675; called by muse, mutect2, varscan2
- ZBTB16 | c.537C>T p.P179= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs368971745; called by muse, mutect2, varscan2
- ZNF615 | c.1311C>T p.F437= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as rs769359683, COSV65034071; called by muse, mutect2, varscan2
- ZNF880 | c.1119C>T p.I373= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs77886189; called by muse, mutect2, varscan2
- AGAP7P | n.1675C>T | RNA (SNP) | VAF 71/113 reads (63%) | called by muse, mutect2, varscan2
- ALKBH6 | c.-145G>A | 5'UTR (SNP) | VAF 19/40 reads (48%) | catalogued as rs762105505, COSV53325183; called by muse, mutect2, varscan2
- CHCHD2P9 | n.43C>T | RNA (SNP) | VAF 12/47 reads (26%) | catalogued as rs747218582; called by muse, mutect2, varscan2
- CLCA3P | n.484G>A | RNA (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- DPP6 | c.627+21115G>A | Intron (SNP) | VAF 138/179 reads (77%) | called by muse, mutect2
- FAM183BP | n.954G>A | RNA (SNP) | VAF 41/73 reads (56%) | called by muse, mutect2, varscan2
- GPHN | c.729+1312C>T | Intron (SNP) | VAF 22/30 reads (73%) | catalogued as rs1251870900; called by muse, mutect2, varscan2
- HERC2P3 | n.665G>A | RNA (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2, varscan2
- HMGB1P1 | n.585G>A | RNA (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.4G>A | RNA (SNP) | VAF 6/16 reads (38%) | catalogued as rs1310448474; called by mutect2, varscan2
- KCNN2 | c.*2A>G | 3'UTR (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99299992; called by muse, mutect2, varscan2
- MEF2C | c.402+109C>T | Intron (SNP) | VAF 24/98 reads (24%) | catalogued as rs1007520458, COSV60934288; called by muse, mutect2, varscan2
- MIR587 | n.47G>A | RNA (SNP) | VAF 39/50 reads (78%) | called by muse, mutect2, varscan2
- TTN | c.10303+1303C>T | Intron (SNP) | VAF 44/114 reads (39%) | catalogued as COSV100633439; called by muse, mutect2, varscan2
- ZFHX3 | c.-533+149G>C | Intron (SNP) | VAF 17/66 reads (26%) | catalogued as rs766759142, COSV73947921; called by muse, mutect2, varscan2
